Somatic mutation profile of tumor specimen C3N-02693-01 (aliquot CPT0226130006) from CPTAC case C3N-02693, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 43.0 years (15,703 days).
Specimen C3N-02693-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18ffb107-7167-4bc9-9352-7487f88f5904.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02693-31 (Blood Derived Normal), aliquot CPT0226170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9d4f981-bcd8-4b9c-8c06-f90691e8453a

The open-access MAF lists 243 somatic variants for this specimen: 141 protein-altering or splice-affecting, 66 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 66, Intron 15, Nonsense Mutation 14, RNA 8, 3'UTR 5, 5'UTR 5, Splice Site 2, Frame Shift Ins 2, 5'Flank 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 33/79 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AGAP2 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 118/393 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as COSV57727453; called by muse, mutect2, varscan2
- AKAP9 | c.10583G>A p.G3528E (on ENST00000359028; = p.G3504E on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as rs1381203501; called by muse, mutect2, varscan2
- ANKRD40 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV53320105, COSV53330741; called by muse, mutect2, varscan2
- ARHGAP32 | c.2715G>A p.M905I (on ENST00000310343 / NM_001378025.1; = p.M556I on NM_014715.4) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59850502; called by muse, mutect2, varscan2
- ATL1 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV63297839; called by muse, mutect2, varscan2
- BTBD1 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 90/331 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV99915481; called by muse, mutect2, varscan2
- C8A | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV63485181; called by muse, mutect2, varscan2
- CACNA1F | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV59906692; called by muse, mutect2, varscan2
- CCDC102B | c.810C>G p.I270M | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV60150122; called by muse, mutect2, varscan2
- CD58 | c.502C>G p.R168G | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59841507, COSV59841764; called by muse, mutect2, varscan2
- CFAP47 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775602003, COSV52888789; called by muse, mutect2
- CHDH | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 87/288 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs778513992, COSV59460269; called by muse, mutect2, varscan2
- CLCNKA | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 133/410 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746559971; called by muse, mutect2, varscan2
- CMSS1 | c.761G>C p.R254T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs1296721161; called by muse, mutect2, varscan2
- CNTN6 | c.2023G>A p.V675I | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1444575291; called by muse, varscan2
- COLGALT2 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs766695811; called by muse, mutect2, varscan2
- CPSF1 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1230158853; called by muse, mutect2, varscan2
- CR2 | c.787G>A p.V263I | Missense Mutation (SNP) | VAF 122/430 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs750148498; called by muse, mutect2, varscan2
- CUEDC2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 108/275 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs372005158, COSV50041722, COSV99193899; called by mutect2, varscan2
- DHX57 | c.3814C>G p.Q1272E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.105); catalogued as COSV54885273; called by muse, mutect2, varscan2
- DNAH3 | c.7360G>A p.E2454K | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.772); catalogued as rs745652716; called by muse, mutect2, varscan2
- ERAL1 | c.480G>C p.E160D | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs777926902; called by muse, mutect2, varscan2
- ETV3 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 106/212 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1166194726; called by muse, mutect2, varscan2
- FBN3 | c.3041C>T p.A1014V | Missense Mutation (SNP) | VAF 97/309 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs756579395, COSV54470384; called by muse, mutect2, varscan2
- FBXL5 | c.1547C>T p.S516F | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1254728759; called by muse, mutect2, varscan2
- FDX2 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.097); catalogued as rs1285711358, COSV100593850; called by muse, mutect2, varscan2
- GRM3 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.999); catalogued as COSV64469601; called by muse, mutect2, varscan2
- HLA-A | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 166/702 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as rs11539959; called by muse, varscan2
- HLA-A | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 70/272 reads (26%) | catalogued as COSV65142704; called by muse, mutect2
- HYAL4 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.745); catalogued as COSV99772452; called by muse, mutect2, varscan2
- HYDIN | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55500115; called by muse, mutect2, varscan2
- IFNAR1 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1332193148, COSV54254538; called by muse, mutect2, varscan2
- IMPDH1 | c.170G>A p.R57Q (on ENST00000470772 / NM_001142573.2; = p.R142Q on NM_000883.4) | Missense Mutation (SNP) | VAF 168/580 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs552026245; called by muse, mutect2, varscan2
- KIAA1522 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1019026738; called by muse, mutect2, varscan2
- LRBA | c.6898C>T p.H2300Y | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100842008, COSV63955193; called by muse, mutect2, varscan2
- LRFN5 | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 72/294 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV99985037; called by muse, mutect2
- MAGEB18 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.577); catalogued as COSV100305486, COSV100305495; called by muse, mutect2, varscan2
- MEAK7 | c.800G>A p.C267Y | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs572528553, COSV100640449; called by muse, mutect2, varscan2
- MGAT5B | c.2020C>T p.R674W (on ENST00000569840 / NM_001199172.2; = p.R672W on NM_144677.3) | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.292); catalogued as rs375795136; called by muse, mutect2, varscan2
- MICALL2 | c.391G>C p.G131R | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs781357571; called by muse, mutect2, varscan2
- MIPOL1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs778977887; called by muse, mutect2, varscan2
- MUC16 | c.34057C>T p.H11353Y | Missense Mutation (SNP) | VAF 74/261 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs765764561; called by muse, mutect2, varscan2
- MUC17 | c.1225G>C p.E409Q | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.093); catalogued as COSV60287055; called by muse, mutect2, varscan2
- MUC5B | c.14675C>G p.S4892C | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as rs942702113; called by muse, mutect2, varscan2
- MYH2 | c.868dup p.Y290Lfs*7 | Frame Shift Ins (INS) | VAF 14/71 reads (20%) | catalogued as rs1440820907; called by mutect2, pindel, varscan2
- NCOR2 | c.2290C>T p.Q764* | Nonsense Mutation (SNP) | VAF 51/179 reads (28%) | catalogued as COSV62299521; called by muse, mutect2, varscan2
- NPHP4 | c.2437G>A p.V813I | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs781705623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OS9 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs765826209; called by mutect2, varscan2
- PCDHA1 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 138/489 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as COSV65374644; called by muse, mutect2, varscan2
- PCMTD2 | c.778C>T p.H260Y | Missense Mutation (SNP) | VAF 68/324 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV55063060; called by muse, mutect2, varscan2
- PCSK5 | c.1287G>A p.W429* | Nonsense Mutation (SNP) | VAF 29/135 reads (21%) | catalogued as COSV65084020; called by muse, mutect2, varscan2
- PIGN | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV62950988; called by muse, varscan2
- PLCH2 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs766498995; called by muse, mutect2, varscan2
- PLIN2 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs759915698, COSV52804309; called by muse, mutect2, varscan2
- RAB3B | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 55/174 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100784870; called by muse, mutect2, varscan2
- RBL1 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 65/194 reads (34%) | catalogued as rs1568869488; called by muse, mutect2, varscan2
- RIMS2 | c.4540C>T p.P1514S (on ENST00000666250 / NM_001348490.2; = p.P1085S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777274508, COSV99167522; called by muse, mutect2, varscan2
- SENP2 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 53/247 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.916); catalogued as rs772605303, COSV56192347; called by muse, mutect2, varscan2
- SERPINA4 | c.903G>A p.W301* | Nonsense Mutation (SNP) | VAF 34/92 reads (37%) | catalogued as rs1163842908, COSV54070758; called by muse, mutect2, varscan2
- SMARCA4 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 59/158 reads (37%) | catalogued as COSV60788373; called by muse, mutect2, varscan2
- SMC4 | c.1672-1G>A p.X558_splice | Splice Site (SNP) | VAF 10/43 reads (23%) | catalogued as COSV61008260; called by muse, mutect2, varscan2
- SPTBN5 | c.5501G>A p.R1834Q | Missense Mutation (SNP) | VAF 71/255 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.047); catalogued as rs747046857; called by muse, mutect2, varscan2
- SQLE | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 13/49 reads (27%) | catalogued as rs1185564822; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 24/91 reads (26%) | PolyPhen benign (0.019); catalogued as rs772659772, COSV60347050; called by muse, mutect2, varscan2
- SVEP1 | c.4526G>C p.R1509T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV57046155; called by muse, mutect2, varscan2
- TGM2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 123/570 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs776311789, COSV63932097; called by muse, mutect2, varscan2
- TMEM63B | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1486548347; called by muse, mutect2, varscan2
- TYK2 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as rs1342998501, COSV53388603; called by muse, mutect2, varscan2
- VPS45 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 38/88 reads (43%) | catalogued as rs1553802031; called by muse, mutect2
- YTHDF3 | c.1432G>A p.E478K | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV72773752; called by muse, mutect2, varscan2
- ZFP36L2 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 119/388 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.381); catalogued as rs941484401, COSV56700594; called by muse, mutect2, varscan2
- ZNF595 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781894376, COSV59551783; called by muse, mutect2
- ZNF701 | c.1382C>T p.S461L (on ENST00000301093; = p.S395L on NM_018260.3) | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs267605639, COSV56525094; called by muse, mutect2, varscan2
- ZNFX1 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen possibly damaging (0.689); catalogued as rs1445932040; called by muse, mutect2, varscan2
- ACTRT3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS10 | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ANK3 | c.11069G>C p.G3690A | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKZF1 | c.1863G>T p.Q621H | Missense Mutation (SNP) | VAF 121/430 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ARMT1 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ASTN2 | c.1506G>T p.Q502H (on ENST00000313400 / NM_001365069.1; = p.Q451H on NM_014010.5) | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- BRSK1 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 69/190 reads (36%) | called by muse, mutect2, varscan2
- BTBD18 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- C4orf54 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- CCDC179 | c.203C>G p.S68C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- CFAP92 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL3A1 | c.3697G>A p.E1233K | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- CTAGE8 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 37/423 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYP1B1 | c.1452C>G p.I484M | Missense Mutation (SNP) | VAF 154/497 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- DSG3 | c.2776C>G p.L926V | Missense Mutation (SNP) | VAF 76/254 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ENPP2 | c.1522G>A p.E508K (on ENST00000075322 / NM_001040092.3; = p.E560K on NM_006209.5) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC6L2 | c.2616G>C p.Q872H | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- FAM180B | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 79/235 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXW12 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FLNB | c.3129G>A p.V1043= | Splice Region (SNP) | VAF 57/244 reads (23%) | called by muse, varscan2
- FOLR1 | c.491C>A p.S164* | Nonsense Mutation (SNP) | VAF 137/410 reads (33%) | called by muse, mutect2, varscan2
- FSHR | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDI1 | c.1108C>G p.L370V | Missense Mutation (SNP) | VAF 70/111 reads (63%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- HIVEP1 | c.644C>A p.S215* | Nonsense Mutation (SNP) | VAF 25/121 reads (21%) | called by muse, mutect2, varscan2
- HNRNPUL1 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2
- HSDL2 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HYDIN | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); called by mutect2, varscan2
- IFT46 | c.208G>C p.E70Q (on ENST00000264021 / NM_001168618.2; = p.E121Q on NM_020153.3) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- IGLV10-54 | c.37C>G p.H13D | Missense Mutation (SNP) | VAF 111/545 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- IL2RB | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAZALD1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 119/275 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- KIF2B | c.1358G>C p.R453T | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMC1 | c.3850-1G>A p.X1284_splice | Splice Site (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- LOXHD1 | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- LRRC14B | c.1418_1419insA p.T474Hfs*8 | Frame Shift Ins (INS) | VAF 185/547 reads (34%) | called by mutect2, pindel*, varscan2*
- LRRC37A3 | c.1201C>G p.Q401E | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by mutect2, varscan2
- MCM2 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 101/360 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MCTP1 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- MGAM2 | c.3376C>T p.H1126Y | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MSH5 | c.489G>C p.E163D | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MSH5 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- OR8B3 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTOGL | c.4691G>C p.R1564T (on ENST00000547103; = p.R1555T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- PCDH17 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 148/505 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PHIP | c.3545C>T p.S1182L | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- PNMA3 | c.1284C>G p.I428M | Missense Mutation (SNP) | VAF 100/162 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PRSS36 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 68/265 reads (26%) | called by muse, mutect2, varscan2
- RC3H1 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 200/517 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- RCN2 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RFX7 | c.2245C>T p.Q749* (on ENST00000559447 / NM_001368074.1; = p.Q846* on NM_022841.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 37/131 reads (28%) | called by muse, mutect2, varscan2
- SETBP1 | c.1047C>A p.N349K | Missense Mutation (SNP) | VAF 103/405 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SLCO3A1 | c.2026G>C p.D676H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- SOX4 | c.1198G>C p.E400Q | Missense Mutation (SNP) | VAF 115/420 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- SOX6 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 91/337 reads (27%) | called by mutect2, varscan2
- SPATA31A3 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by mutect2, varscan2
- TAF8 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TENM3 | c.6319G>A p.D2107N | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TGM1 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 114/441 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THAP8 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 60/502 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPTE | c.1204C>A p.H402N (on ENST00000618007 / NM_199261.4; = p.H384N on NM_199259.4) | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UTP6 | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- VSX1 | c.520C>G p.H174D | Missense Mutation (SNP) | VAF 79/180 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ZC3H12A | c.1427C>G p.S476C | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFYVE16 | c.3115G>A p.E1039K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- ZNF676 | c.262G>C p.E88Q (on ENST00000650058; = p.E56Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ZNF736 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ADGRE3 | c.1302C>T p.F434= | Silent (SNP) | VAF 80/264 reads (30%) | called by muse, mutect2, varscan2
- ANAPC2 | c.2043G>A p.L681= | Silent (SNP) | VAF 47/155 reads (30%) | called by muse, mutect2, varscan2
- ANKRD11 | c.3813G>A p.S1271= | Silent (SNP) | VAF 76/261 reads (29%) | catalogued as rs368590420; called by muse, mutect2, varscan2
- ARMH1 | c.96C>T p.L32= | Silent (SNP) | VAF 152/451 reads (34%) | catalogued as rs578252622; called by muse, mutect2, varscan2
- CAMSAP2 | c.270G>A p.K90= | Silent (SNP) | VAF 76/248 reads (31%) | called by muse, mutect2, varscan2
- CASP9 | c.1197G>A p.Q399= | Silent (SNP) | VAF 44/198 reads (22%) | called by muse, mutect2, varscan2
- CDH23 | c.7260C>T p.I2420= | Silent (SNP) | VAF 136/322 reads (42%) | called by muse, mutect2, varscan2
- CKAP5 | c.3069C>G p.L1023= | Silent (SNP) | VAF 42/154 reads (27%) | called by muse, mutect2, varscan2
- CSPG4 | c.6700C>T p.L2234= | Silent (SNP) | VAF 44/176 reads (25%) | catalogued as rs772731131; called by muse, mutect2, varscan2
- EFCAB6 | c.651G>A p.S217= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs768973620, COSV53067490; called by muse, mutect2, varscan2
- EGF | c.309G>A p.L103= | Silent (SNP) | VAF 29/113 reads (26%) | called by muse, mutect2, varscan2
- EGFR | c.2259G>A p.P753= | Silent (SNP) | VAF 34/303 reads (11%) | catalogued as rs764064214, COSV51815487, COSV51844009; called by muse, mutect2, varscan2
- EMC1 | c.1812C>T p.F604= | Silent (SNP) | VAF 47/168 reads (28%) | catalogued as rs1035699101; called by muse, mutect2, varscan2
- F5 | c.3759C>T p.L1253= | Silent (SNP) | VAF 217/508 reads (43%) | called by muse, mutect2, varscan2
- FBXL7 | c.510C>T p.L170= | Silent (SNP) | VAF 145/471 reads (31%) | called by muse, mutect2, varscan2
- FOXO3 | c.534C>T p.L178= | Silent (SNP) | VAF 76/268 reads (28%) | catalogued as rs757795843; called by muse, mutect2, varscan2
- FSCN3 | c.1359C>T p.L453= | Silent (SNP) | VAF 62/237 reads (26%) | called by muse, mutect2, varscan2
- GDI1 | c.1149C>T p.I383= | Silent (SNP) | VAF 193/327 reads (59%) | catalogued as rs782501562; called by muse, mutect2, varscan2
- HELZ2 | c.3345G>A p.P1115= (on ENST00000467148 / NM_001037335.2; = p.P546= on NM_033405.3) | Silent (SNP) | VAF 79/394 reads (20%) | catalogued as rs762786259; called by muse, mutect2, varscan2
- IQSEC1 | c.765C>T p.D255= | Silent (SNP) | VAF 63/190 reads (33%) | catalogued as rs146221387; called by muse, mutect2, varscan2
- ITPR3 | c.4536G>A p.P1512= | Silent (SNP) | VAF 90/283 reads (32%) | catalogued as rs773138921, COSV65409205; called by muse, mutect2, varscan2
- KIAA1549L | c.4374C>T p.T1458= (on ENST00000321505; = p.T1755= on NM_012194.3) | Silent (SNP) | VAF 52/139 reads (37%) | catalogued as rs750034764; called by muse, mutect2, varscan2
- KLC3 | c.1410G>A p.L470= | Silent (SNP) | VAF 65/209 reads (31%) | catalogued as rs745770069; called by muse, mutect2, varscan2
- LMF1 | c.1656G>A p.L552= | Silent (SNP) | VAF 67/218 reads (31%) | catalogued as COSV99234936; called by muse, mutect2, varscan2
- LPP | c.1815C>T p.T605= | Silent (SNP) | VAF 25/183 reads (14%) | catalogued as rs570800629; called by muse, mutect2, varscan2
- MAP1B | c.993C>T p.L331= | Silent (SNP) | VAF 74/269 reads (28%) | catalogued as rs145044773; called by muse, mutect2, varscan2
- MICU2 | c.1215G>A p.Q405= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV66673088; called by muse, mutect2, varscan2
- MRTFA | c.2637G>A p.P879= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs371656671, COSV99960540; called by muse, mutect2
- MYCBP2 | c.4440G>A p.V1480= (on ENST00000357337; = p.V1518= on NM_015057.5) | Silent (SNP) | VAF 32/132 reads (24%) | called by muse, mutect2, varscan2
- NEGR1 | c.876C>T p.F292= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs766137505, COSV60842675; called by muse, mutect2
- OR2AJ1 | c.213C>T p.I71= | Silent (SNP) | VAF 53/208 reads (25%) | called by muse, mutect2, varscan2
- OTOGL | c.3852C>T p.L1284= (on ENST00000547103; = p.L1275= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/125 reads (30%) | called by muse, mutect2, varscan2
- PDE4A | c.1575C>G p.L525= (on ENST00000380702 / NM_001111307.2; = p.L286= on NM_006202.3) | Silent (SNP) | VAF 60/239 reads (25%) | called by muse, mutect2, varscan2
- PMEPA1 | c.846G>A p.Q282= | Silent (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- POM121 | c.3597C>T p.L1199= (on ENST00000434423; = p.L934= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/184 reads (17%) | catalogued as rs369254873; called by muse, mutect2, varscan2
- PPIC | c.9G>A p.P3= | Silent (SNP) | VAF 108/295 reads (37%) | called by muse, mutect2, varscan2
- PPP1R13L | c.2433G>A p.P811= | Silent (SNP) | VAF 77/248 reads (31%) | catalogued as rs753361779, COSV62909853; called by muse, mutect2, varscan2
- PYGL | c.162C>T p.F54= | Silent (SNP) | VAF 116/379 reads (31%) | catalogued as rs999162918; called by muse, mutect2
- RARA | c.918C>T p.T306= | Silent (SNP) | VAF 144/438 reads (33%) | catalogued as rs956783037; called by muse, mutect2, varscan2
- RBM19 | c.1773C>T p.V591= | Silent (SNP) | VAF 66/217 reads (30%) | called by muse, mutect2, varscan2
- RNF19B | c.702G>A p.Q234= | Silent (SNP) | VAF 103/384 reads (27%) | called by muse, mutect2, varscan2
- RREB1 | c.2481C>T p.A827= | Silent (SNP) | VAF 92/290 reads (32%) | catalogued as rs773711706; called by muse, mutect2, varscan2
- RXFP1 | c.384G>A p.V128= | Silent (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- RYR1 | c.5577G>A p.V1859= | Silent (SNP) | VAF 88/322 reads (27%) | catalogued as COSV62108293; called by muse, mutect2, varscan2
- SCPEP1 | c.1062C>T p.D354= | Silent (SNP) | VAF 56/259 reads (22%) | catalogued as rs142043086; called by muse, mutect2, varscan2
- SGCE | c.1299C>T p.I433= (on ENST00000647096; = p.I397= on NM_003919.3) | Silent (SNP) | VAF 46/218 reads (21%) | catalogued as COSV56022209; called by muse, mutect2, varscan2
- SHPK | c.676C>T p.L226= | Silent (SNP) | VAF 56/171 reads (33%) | called by mutect2, varscan2
- SLC22A4 | c.480C>A p.S160= | Silent (SNP) | VAF 79/306 reads (26%) | called by muse, mutect2, varscan2
- SLC35F5 | c.48G>A p.L16= | Silent (SNP) | VAF 35/133 reads (26%) | catalogued as rs908374197; called by muse, mutect2, varscan2
- SLC4A8 | c.184C>A p.R62= | Silent (SNP) | VAF 38/117 reads (32%) | called by muse, mutect2, varscan2
- SPNS1 | c.276C>T p.I92= | Silent (SNP) | VAF 66/269 reads (25%) | called by muse, mutect2, varscan2
- SPTSSA | c.48C>T p.F16= | Silent (SNP) | VAF 104/395 reads (26%) | called by muse, mutect2, varscan2
- STAG3 | c.1527G>A p.L509= | Silent (SNP) | VAF 87/303 reads (29%) | called by muse, mutect2, varscan2
- SULF1 | c.1101G>A p.T367= | Silent (SNP) | VAF 65/236 reads (28%) | catalogued as rs146417849; called by muse, mutect2, varscan2
- SYT5 | c.388C>T p.L130= | Silent (SNP) | VAF 41/166 reads (25%) | catalogued as COSV100845868, COSV62829595; called by muse, mutect2, varscan2
- TNFSF18 | c.567C>T p.I189= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- TOGARAM1 | c.1377C>T p.F459= | Silent (SNP) | VAF 30/83 reads (36%) | called by muse, mutect2, varscan2
- TRPV1 | c.2037C>T p.L679= | Silent (SNP) | VAF 85/294 reads (29%) | catalogued as rs951719522; called by muse, mutect2, varscan2
- UNC13B | c.2772G>A p.V924= | Silent (SNP) | VAF 49/207 reads (24%) | called by muse, mutect2, varscan2
- UNC5CL | c.1188A>G p.P396= | Silent (SNP) | VAF 75/258 reads (29%) | called by muse, mutect2, varscan2
- URB1 | c.1692C>T p.L564= | Silent (SNP) | VAF 49/180 reads (27%) | called by muse, mutect2, varscan2
- VPS33B | c.1389G>A p.V463= | Silent (SNP) | VAF 126/411 reads (31%) | catalogued as COSV100325716; called by muse, mutect2, varscan2
- WIPF3 | c.1011G>A p.P337= | Silent (SNP) | VAF 32/137 reads (23%) | catalogued as rs1350096370; called by muse, mutect2, varscan2
- WWC2 | c.2817G>A p.G939= | Silent (SNP) | VAF 31/106 reads (29%) | called by muse, mutect2, varscan2
- ZNF829 | c.861G>C p.L287= | Silent (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- ZZEF1 | c.2457C>A p.I819= | Silent (SNP) | VAF 70/260 reads (27%) | called by muse, mutect2, varscan2
- AK2 | c.*4043C>T | 3'UTR (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- AL732372.2 | n.151+2447C>T | Intron (SNP) | VAF 68/606 reads (11%) | catalogued as rs779461007; called by muse, mutect2, varscan2
- ARID2 | chr12:45727598 G>A | 5'Flank (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- ATAD3B | c.*97C>T | 3'UTR (SNP) | VAF 66/301 reads (22%) | catalogued as rs1174816379, COSV58021945; called by muse, mutect2, varscan2
- CCDC88A | c.5551+389G>T | Intron (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- CHCHD1 | c.243+37G>C | Intron (SNP) | VAF 37/157 reads (24%) | catalogued as COSV100863382; called by muse, mutect2, varscan2
- COG1 | c.-12G>A | 5'UTR (SNP) | VAF 63/234 reads (27%) | catalogued as rs887631897; called by muse, mutect2, varscan2
- CPS1 | c.528+11C>T | Intron (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- CYGB | c.*927C>T | 3'UTR (SNP) | VAF 116/502 reads (23%) | called by muse, mutect2, varscan2
- DCLRE1CP1 | n.167C>A | RNA (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- DCUN1D4 | c.-37G>A | 5'UTR (SNP) | VAF 76/245 reads (31%) | called by muse, mutect2, varscan2
- FAS | c.*104G>C | 3'UTR (SNP) | VAF 52/148 reads (35%) | catalogued as CM004283, CM085399, CM961372, COSV58239202, COSV58239697; called by muse, mutect2, varscan2
- FMR1 | c.*999C>T | 3'UTR (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- GALT | c.328+12C>T | Intron (SNP) | VAF 187/656 reads (29%) | catalogued as rs1230730695; called by muse, mutect2, varscan2
- KCNA1 | c.-17C>T | 5'UTR (SNP) | VAF 53/180 reads (29%) | catalogued as rs746212583, COSV66836806; called by muse, mutect2, varscan2
- LINC00518 | n.903C>T | RNA (SNP) | VAF 39/119 reads (33%) | catalogued as rs1382940304; called by muse, mutect2, varscan2
- LINC01558 | n.306C>T | RNA (SNP) | VAF 136/265 reads (51%) | called by muse, mutect2, varscan2
- LIPH | c.49+5489G>A | Intron (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- MCFD2 | c.309+32C>T | Intron (SNP) | VAF 64/259 reads (25%) | called by muse, mutect2, varscan2
- MIR573 | n.37C>T | RNA (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.1326C>T | RNA (SNP) | VAF 83/273 reads (30%) | called by muse, mutect2, varscan2
- OR2W5 | n.687C>T | RNA (SNP) | VAF 117/422 reads (28%) | called by muse, mutect2, varscan2
- PBLD | c.754+43C>T | Intron (SNP) | VAF 14/94 reads (15%) | catalogued as rs373206447; called by muse, mutect2
- PRDM11 | chr11:45228150 C>T | 3'Flank (SNP) | VAF 22/69 reads (32%) | catalogued as rs779681936; called by muse, mutect2, varscan2
- PTENP1 | n.1971G>A | RNA (SNP) | VAF 42/164 reads (26%) | called by muse, mutect2, varscan2
- PTPRM | c.-51C>T | 5'UTR (SNP) | VAF 25/77 reads (32%) | catalogued as rs774947124, COSV100160967; called by muse, mutect2, varscan2
- RANBP1 | c.310+191G>A | Intron (SNP) | VAF 104/347 reads (30%) | catalogued as rs1321034462; called by muse, mutect2, varscan2
- RNGTT | chr6:88966076 G>A | 5'Flank (SNP) | VAF 57/194 reads (29%) | called by muse, mutect2, varscan2
- RPL3 | c.3+55C>T | Intron (SNP) | VAF 70/266 reads (26%) | called by muse, mutect2, varscan2
- SEMA4A | c.568+16C>T | Intron (SNP) | VAF 180/405 reads (44%) | called by muse, mutect2, varscan2
- SLC47A1P2 | n.340C>G | RNA (SNP) | VAF 37/126 reads (29%) | called by muse, mutect2, varscan2
- ST20-MTHFS | c.-12+423C>T | Intron (SNP) | VAF 38/152 reads (25%) | catalogued as COSV72103122; called by muse, mutect2, varscan2
- SUN1 | c.658+72C>T | Intron (SNP) | VAF 26/105 reads (25%) | called by muse, mutect2, varscan2
- TRIM22 | c.751-30C>T | Intron (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- VKORC1 | c.173+177G>A | Intron (SNP) | VAF 71/252 reads (28%) | catalogued as COSV56231803, COSV56232505; called by muse, mutect2, varscan2
- ZNF584 | c.-74G>A | 5'UTR (SNP) | VAF 33/132 reads (25%) | called by muse, mutect2, varscan2
